TCGA case TCGA-HI-7171 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/931feb14-3f69-41c1-8435-5fd4fb775bdf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Dead; Days to death: 1,329 days (3.6 years).

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 56.9 years (20,776 days); Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC clinical T: T3a; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; Primary gleason grade: Pattern 5; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 7; Tumor level prostate: Apex / Middle / Base.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Initial disease status: Recurrent Disease; Days to treatment start: 559 days (1.5 years); Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Ketoconazole; Initial disease status: Recurrent Disease; Days to treatment start: 648 days (1.8 years); Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Bicalutamide; Initial disease status: Recurrent Disease; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Initial disease status: Recurrent Disease; Route of administration: Intramuscular.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Course number: 1; Treatment anatomic sites: Locoregional Site.

Follow-up (7 entries)
- Days to follow up: 218 days; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 218 days.
- Days to follow up: 543 days (1.5 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 543 days (1.5 years).
- Days to follow up: 631 days (1.7 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 631 days (1.7 years).
- Days to follow up: 1,329 days (3.6 years); Disease response: With Tumor.
- Imaging type: MRI; Imaging findings: No Evidence of Extraprostatic Extension; Timepoint: Initial Diagnosis.
- Imaging type: Bone Scan, NOS; Imaging result: Negative; Timepoint: Initial Diagnosis.
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.7 ng/mL (day 631).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HI-7171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1; Shortest dimension: 0.3.
  Slide TCGA-HI-7171-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-HI-7171-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-HI-7171-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HI-7171-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: No; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Biochemical recurrence indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.7.
- Stage record, Gleason grading: Gleason pattern primary: 5; Gleason pattern secondary: 4.
- Drug treatment 1: Regimen number: 3; Therapy regimen: Recurrence.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Lupron; Therapy regimen: Recurrence.
- Drug treatment 2, Route of administrations: Route of administration: IM.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Casodex; Therapy regimen: Recurrence.
- Drug treatment 4: Regimen number: 0; Pharmaceutical therapy drug name: Casodex; Therapy regimen: Recurrence.
- Drug treatment 4, Route of administrations: Route of administration: SC.
- Follow-up form: Treatment outcome first course: Stable Disease; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,329 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,329 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,329 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HI-7171-01A-12D-2112-01): tumor purity 0.88, ploidy 1.89, whole-genome doublings 0.
